Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A719, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A719-01A (Primary Tumor).

ICD O-3
Carcinoma, squamous cell NO
867613
Site Floor mouth
CD4-9
JW 8/9/13

Collect date
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Floor of mouth

1 - "Lymph Nodes – Level 1a- Right":

- Absence of neoplasia: (0/1)

2 - "Lymph Nodes – Level 2a- Right":

- Absence of neoplasia: (0/5)

3 - "Lymph Nodes – Level 3- Right:

- Absence of neoplasia: (0/1)

4 - "Lymph Nodes – Level 1b- Right":

- Absence of neoplasia: (0/6)

- Salivary gland, chronic nonspecific intense sialadenitis, free of neoplastic involvement.

5- "Right Pelvi-glossectomy":

- Squamous cell carcinoma
- Histologic grade: well differentiated
- Tumor size (greatest dimension): 3,5 cm
- Tumor thickness/depth of invasion: 1,0 cm
- Moderate chronic inflammatory infiltrate
- Infiltration of minor salivary gland
- Perineural invasion: not identified
- Lymph-vascular invasion: not identified
- Margins uninvolved by invasive tumor

Dual/S; achronous Primary Noted		✓

Source: NCI Genomic Data Commons file 05932a18-ffe7-4c48-8ae6-4a1986b5e958 (TCGA-UF-A719.31044638-B109-4392-88F9-8C3FA16C6438.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).